Surgical pathology report (de-identified scan), TCGA case TCGA-CI-6622, project TCGA-READ (Rectum Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-CI-6622-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Rectal bleeding, diverticulosis, rectal mass
PROCEDURE: Colonoscopy with biopsy.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

, OTHER DISEASES: Not answered.

TCGA - CI - 6622

FINAL DIAGNOSIS:

RECTUM, MASS, BIOPSY -

INVASIVE ADENOCARCINOMA, WELL-TO-MODERATELY DIFFERENTIATED.

Source: NCI Genomic Data Commons file 85dc88c7-2c92-4ce8-9987-aebdb018da75 (TCGA-CI-6622.61BD660B-AA14-41F6-A6A4-2FEF072D3A10.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).